CGCI case HTMCP-03-06-02268 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/10b32c37-0e82-47e8-8ff8-91a14971737f

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 29 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 29.4 years (10,732 days); Year of diagnosis: 2016; Method of diagnosis: Biopsy; AJCC clinical T: T3b; AJCC clinical N: N1; FIGO stage: Stage IIIB; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 665 days (1.8 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 629 days (1.7 years); Days to treatment end: 665 days (1.8 years); Treatment dose: 50.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Treatment dose: 1600; Treatment anatomic sites: Cervix.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 5000; Treatment anatomic sites: Pelvis.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 194 days; Disease response: With Tumor.
- Days to follow up: 665 days (1.8 years); Disease response: With Tumor.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day 0: Pregnancy outcome: Miscarriage.
- Day 0: Weight: 57.3 kg; Height: 162.9 cm; BMI: 21.6; CD4 count: 779; Haart treatment indicator: Yes; HIV viral load: 0; Hormonal contraceptive use: Former User; Hysterectomy type: Not Performed; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Day 0: Nadir CD4 count: 341.
- Comorbidities: HIV/AIDS.
- Risk factors: HIV/AIDS.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-03-06-02268-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02268-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02268-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Weight kg at diagnosis: 57.3 kg; History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 02; Pregnancies count miscarriage: 01; Pregnancies count induced abortion: 00; Pregnancies count ectopic: 00; Pregnancies count stillbirth: 00; Total pregnancy count: 03; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Squamous Cell Carcinoma, Keratinizing; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Year of HIV diagnosis: 2011; Nadir cd4 counts: 0341; HIV rna load at diagnosis: 0; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes; Cd4 counts at diagnosis: 0779.
- Follow-up form 1, Treatment, Radiation therapy info: Radiation treatment reason not completed other: Patient did not return for follow up.
- Follow-up form 2, Treatment, Radiation therapy info: Brachytherapy type: HDR; Radiation therapy xrt type: External beam radiation.
- Treatments, Treatment 1: Therapy regimen: Initial; Treatment type: No Treatment.
- Treatments, Treatment 2: Therapy regimen: Initial; Treatment type: Radiation Therapy; Radiation therapy end: Yes; Radiation therapy total dosage: 50.
